ALCHEMIST case ALCH-B36O — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/bdad98b2-0185-43e9-ad7d-51e7c2222fdb

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 55.9 years (20,402 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B36O-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B36O-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B36O-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 62; Percent normal cells: 4; Percent necrosis: 2; Percent stromal cells: 5; Percent lymphocyte infiltration: 28; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
